Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KP, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KP-01A (Primary Tumor).

ICD-O-3

Procedure: L adrenalectomy

Gross description: 10 x 8 x 8.5cm, 196g

Diagnosis: adrenocortical carcinoma

Reference Pathology:

Diagnosis: adrenocortical carcinoma

Weiss score: 6

Hough score: 3.9

Van Slooten score: 9

Carcinoma, adrenal cortical
8370/3
Site (L) Adrenal Gland,
Cortex C74.0
JPD 2/6/13

ICDAA Discrepancy		

Source: NCI Genomic Data Commons file ad892f98-f49e-46d8-a19b-3aead3974f4f (TCGA-OR-A5KP.C07E8EA7-A221-40F9-9D19-A59DE0E52200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).